Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A927, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A927-01A (Primary Tumor).

ICD 0-3
Adenocarcinoma, diffuse type
8145/3
Site Body of stomach C16.2
9/5 3/18/14

PRIMARY SITE: Stomach (Body)

- 1 - "Lesion in transverse colon":
- Fragment of autolysed adipose tissue.
- 2 - "Chain 5 lymph nodes":
- Fragment of congested fibroadipose tissue (0/0).
- 3 - "Chain 3 lymph node":
- Fragment of congested fibroadipose tissue (0/0).
- 4 - "Stomach and omentum":
- Poorly differentiated adenocarcinoma, diffuse pattern of Laurén, measuring 16.5 cm in extension, infiltrating the wall up to perigastric adipose tissue;
- Presence of perineural invasion;
- Presence of angiolymphatic invasion;
- Proximal margin compromised by the neoplasia;
- Distal margin is free of neoplasia, but is exiguous (<1.0 mm);
- Fragment of epiplon constituted of mature adipose tissue, free of neoplasia in the sample;
- Metastatic carcinoma in 13 of 13 dissected lymph nodes, with capsular transposition (16/16);
- Metastatic carcinoma in 11 of 11 dissected lymph nodes with capsular transposition (11/11).

Topography	Morphology	Stage
Stomach, NOS	Adenocarcinoma, NOS	pT3 pN3b

[illegible]

Source: NCI Genomic Data Commons file 25825562-d66f-4b26-85c1-31e2d66a1f22 (TCGA-VQ-A927.4502F035-E34D-4C29-9AC5-2D4463E8753A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).